Somatic mutation profile of tumor specimen TCGA-MK-A4N6-01A (aliquot TCGA-MK-A4N6-01A-11D-A257-08) from TCGA case TCGA-MK-A4N6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.3 years (12,904 days).
Specimen TCGA-MK-A4N6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45cfdaf8-cfd4-482b-87b1-1a3d4272754b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MK-A4N6-10A (Blood Derived Normal), aliquot TCGA-MK-A4N6-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce4aa0df-8e5f-4a7c-a1b3-ed964979968f

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BMP1 | c.1843A>T p.K615* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV60476108; called by muse, mutect2, varscan2
- KIF4B | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70527139; called by muse, mutect2, varscan2
- KLHL26 | c.1745A>T p.N582I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV56316120; called by muse, mutect2, varscan2
- KMT2A | c.8335A>G p.K2779E | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.1); catalogued as COSV63281590; called by muse, mutect2, varscan2
- SLCO6A1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs773104457, COSV65805365; called by muse, mutect2, varscan2
- BACH1 | c.1972del p.S658Vfs*71 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- CREBZF | c.873G>A p.L291= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV52628885; called by muse, mutect2
- GLOD5 | c.387A>G p.P129= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs1371862146, COSV57488712; called by muse, mutect2, varscan2
- IGKV1-9 | c.42G>C p.L14= | Silent (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.960G>A p.V320= (on ENST00000352766; = p.V241= on NM_181334.5) | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV61231554; called by muse, mutect2
